Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QD, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QD-01A (Primary Tumor).

[page 1 of 7]
		3/14/11

Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Papillary carcinoma of right lobe thyroid, 2.4 cm complex on ultrasound.

Specimens Submitted:

- 1: Right level three, four, and five lymph nodes; excision
- 2: Delphian lymph node; excision
- 3: Pretracheal and superior mediastinal lymph node (fs); excision
- 4: Right paratracheal lymph nodes (fs); excision
- 5: Right crico thyroid lymph node; excision
- 6: Additional Delphian lymph node; excision
- 7: Left paratracheal lymph nodes; excision
- 8: Thyroid gland; total thyroidectomy
- 9: Pre-tracheal node; excision
- 10: Right level 2 lymph node neck; excision
- 11: Additional right paratracheal lymph nodes; excision
- 12: Additional left paratracheal lymph nodes; excision

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site, thyroid C73.9 hr 3/14/11

DIAGNOSIS:

1. Right level three, four, and five lymph nodes; excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 9
Number of lymph nodes with metastatic disease: 4
Size of the largest lymph node involved by tumor: 1.6cm.
Size of the largest metastatic focus : 0.5 cm.
Extranodal extension is not identified

2. Delphian lymph node; excision:

Lymph Node Dissection:

Benign thyroid tissue with chronic lymphocytic thyroiditis,

3. Pretracheal and superior mediastinal lymph node (fs); excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.9cm.
Size of the largest metastatic focus : 0.9 cm.
Extranodal extension is identified

4. Right paratracheal lymph nodes (fs); excision:

Lymph Node Dissection:

[page 2 of 7]
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is not identified

5. Right crico thyroid lymph node; excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma.
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.3cm.
Size of the largest metastatic focus : 0.1 cm.
Extranodal extension is not identified

6. Additional Delphian lymph node; excision:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.55cm.
Size of the largest metastatic focus : 0.2 cm.
Extranodal extension is not identified

7. Left paratracheal lymph nodes; excision:

Lymph Node Dissection:

Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 0

8. Thyroid gland; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Marked stromal reaction
Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.2 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

[page 3 of 7]
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

Non-Neoplastic Thyroid:
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:
Identified
One unremarkable parathyroid

Lymph Nodes:
One of six perithyroidal lymph nodes with metastatic papillary thyroid carcinoma

9. Pre-tracheal node; excision:

Lymph Node Dissection:
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 0

10. Right level 2 lymph node neck; excision:

Lymph Node Dissection:
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 0

11. Additional right paratracheal lymph nodes; excision:

Lymph Node Dissection:
Metastatic papillary thyroid carcinoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.45cm.
Size of the largest metastatic focus : 0.3 cm.
Extranodal extension is not identified

12. Additional left paratracheal lymph nodes; excision:

Lymph Node Dissection:
Number of lymph nodes examined: 4
Number of lymph nodes with metastatic disease: 0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 4 of 7]
Gross Description:

1). The specimen is received fresh, labeled "right level three, four and five lymph node neck, fresh and sterile" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 1.3 cm in greatest dimension. All identified lymph nodes are submitted in three cassettes

Summary of sections:

LN - lymph node

2). The specimen is received fresh, labeled "Delphian lymph node, fresh/sterile" and consists of a single irregular portion of pink tan firm soft tissue ranging from 1.4 x 0.6 x 0.3cm in greatest dimension. The lymph node is entirely submitted in one cassette.

Summary of sections:

U -- undesignated

3). The specimen is received fresh for frozen section labeled "pretracheal and superior mediastinal lymph nodes", and consists of one tan yellow fibroadipose tissue measuring 1.7 x 1.1 x 0.3 cm with two possible lymph nodes. Entirely submitted.

Summary of sections:

FS -- frozen section control

4). The specimen is received fresh for frozen section labeled, "right paratracheal lymph nodes", and consists of one tan red lymph node measuring 1.0 x 0.7 x 0.2 cm. Entirely submitted.

Summary of sections:

FS -- frozen section control

5). The specimen is received fresh, labeled "right crico-thyroid lymph node, fresh" and consists of a single pink tan firm lymph node measuring 0.4 x 0.2 x 0.2 cm. The lymph node is entirely submitted in one cassette.

Summary of sections:

LN - lymph node

6). The specimen is received fresh, labeled "additional Delphian lymph node, fresh" and consists of a single pink tan firm lymph node measuring 0.5 x 0.4 x 0.2 cm. The lymph node is entirely submitted in one cassette.

Summary of sections:

LN - lymph node

7) The specimen is received in formalin, labeled "left paratracheal lymph node" and consists of a single pink tan firm lymph node measuring 0.4 cm in greatest dimension. Entirely submitted.

[page 5 of 7]
Summary of sections:
LN - lymph node

8). The specimen is received fresh, labeled "total thyroid, stitch marks right lobe of thyroid" and consists of a thyroid weighing 23 g. The right lobe measures 5.0 x 3.5 x 1.5 cm, the left lobe measures 3.5 x 2.5 x 1.2 cm and the isthmus measures 2.0 x 0.5 x 0.5 cm. The external surface is covered by a thin fibrous capsule and few skeletal muscle anteriorly. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a tan-white hard nodule in the right lobe measuring 2.2 x 1.5 x 1.1 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen is submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
RL - right lobe
LL - left lobe
IS - isthmus

9). The specimen is received in formalin, labeled "pretracheal node" and consists of a single lymph node measuring 0.5 x 0.3 x 0.3 cm. The lymph node is bisected and entirely submitted.

Summary of sections:
BLN - bisected lymph node

10). The specimen is received in formalin, labeled "Right level 2 lymph node(neck)" and consists of a single lymph node measuring 1.1 x 0.7 x 0.3 cm. The lymph node is bisected and entirely submitted.

Summary of sections:
BLN - bisected lymph node

11). The specimen is received in formalin, labeled "Additional pretracheal lymph nodes" and consists of a single lymph node measuring 0.5 x 0.4 x 0.3 cm. The lymph node is bisected and entirely submitted.

Summary of sections:
BLN - bisected lymph node

12). The specimen is received in formalin, labeled "Additional left paratracheal lymph nodes" and consists of a three pink-tan lymph nodes ranging from 0.3cm up to 0.5cm. The lymph nodes and the remaining fatty fibrous tissue is entirely submitted.

Summary of sections:
LN - lymph nodes
U- remaining tissue

Summary of Sections:

Part 1: Right level three, four, and five lymph nodes; excision

[page 6 of 7]
Block	Sect. Site	PCs
4	LN	10

Part 2: Delphian lymph node; excision

Block	Sect. Site	PCs
1	U	1

Part 3: Pretracheal and superior mediastinal lymph node (fs); excision

Block	Sect. Site	PCs
1	FSC	1

Part 4: Right paratracheal lymph nodes (fs); excision

Block	Sect. Site	PCs
1	FSC	1

Part 5: Right crico thyroid lymph node; excision

Block	Sect. Site	PCs
1	LN	1

Part 6: Additional Delphian lymph node; excision

Block	Sect. Site	PCs
1	LN	1

Part 7: Left paratracheal lymph nodes; excision

Block	Sect. Site	PCs
1	ln	1

Part 8: Thyroid gland; total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
6	LL	6
8	RL	8

Part 9: Pre-tracheal node; excision

Block	Sect. Site	PCs
1	BLN	1

Part 10: Right level 2 lymph node neck; excision

Block	Sect. Site	PCs
1	BLN	1

Part 11: Additional right paratracheal lymph nodes; excision

Block	Sect. Site	PCs
1	BLN	1

Part 12: Additional left paratracheal lymph nodes; excision

Block	Sect. Site	PCs
1	LN	1
1	U	1

[page 7 of 7]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 3) FROZEN SECTION DIAGNOSIS: SP: PRETRACHEAL AND SUPERIOR MEDIASTINAL LYMPH NODE (FS):
METASTATIC PAPILLARY THYROID CARCINOMA [REDACTED]
PERMANENT DIAGNOSIS: SAME
- 4) FROZEN SECTION DIAGNOSIS: SP: RIGHT PARATRACHEAL LYMPH NODES (FS): METASTATIC PAPILLARY
THYROID CARCINOMA [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 81c330de-3c0c-4d45-b130-db0110b9f606 (TCGA-DJ-A1QD.600E6160-AB49-4301-BE9F-EAF377C678A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).